Gene-level copy-number profile of tumor specimen C3L-09098-01 from CPTAC case C3L-09098, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 71.0 years (25,949 days).
Specimen C3L-09098-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 19d24da6-4029-4e06-826d-4104ad6dadbd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09098-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/585a4039-6053-4a15-96ad-ff6a95a58996

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,692; copy number 2: 24,967; copy number 3: 21,813; copy number 4: 5,975; copy number 5: 1,284; copy number 6: 838; copy number 7: 422; copy number 8: 168; copy number 9: 8; copy number 10: 27; copy number 11: 45; copy number 12: 66; copy number 13: 16; copy number 17: 31; copy number 139: 2; copy number 153: 13.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:60,021,249–60,033,020, 1 gene (within-gene range 0–1): AC034234.1.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,920 genes in 77 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,418,420–1,745,992, 25 genes, copy number 5: ANKRD65, AL391244.1, TMEM88B, LINC01770, VWA1, ATAD3C, ATAD3B, ATAD3A, TMEM240, SSU72, AL645728.1, AL691432.3, FNDC10, AL691432.2, MIB2, MMP23B, CDK11B, FO704657.1, SLC35E2B, AL691432.1, MMP23A, CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:15,836,095–17,749,978, 79 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:36,339,624–36,630,857, 8 genes, copy number 5: STK40, LSM10, RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R, FTLP18.
- chr1:153,500,463–153,693,992, 18 genes, copy number 5–6: RN7SL44P, BX470102.1, S100A6, S100A5, S100A4, S100A3, S100A2, S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2, NPR1, MIR8083.
- chr1:159,466,321–159,759,589, 10 genes, copy number 5 (within-gene range 2–5): LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2, CRPP1, CRP, AL445528.1.
- chr1:159,854,316–163,321,791, 137 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:221,133,865–224,437,033, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:228,486,188–231,528,618, 90 genes, copy number 5–6 (broad region; genes not listed).
- chr1:234,527,887–236,286,960, 59 genes, copy number 5–11: LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, GPR137B, ERO1B, RNU2-70P, AL450309.1.
- chr2:85,133,392–85,460,252, 20 genes, copy number 5: TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA.
- chr2:87,125,198–87,825,952, 18 genes, copy number 5 (within-gene range 3–5): AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2.
- chr2:102,411,243–102,736,888, 8 genes, copy number 6: SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9.
- chr6:43,243,481–43,510,686, 14 genes, copy number 5 (within-gene range 3–5): TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73.
- chr7:28,953,358–31,421,303, 63 genes, copy number 5 (broad region; genes not listed).
- chr7:45,769,105–45,921,874, 8 genes, copy number 5: GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, IGFBP1, IGFBP3.
- chr8:48,384,590–48,921,740, 12 genes, copy number 7: RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2.
- chr8:144,262,045–144,605,816, 37 genes, copy number 5 (within-gene range 4–5): BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39.
- chr9:136,494,433–136,955,497, 44 genes, copy number 5–6: NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1, RABL6, NCLP1, MIR4292, AJM1, PHPT1, MAMDC4, EDF1, TRAF2, MIR4479, AL807752.1, AL807752.5, FBXW5, C8G, LCN12.
- chr10:31,983,885–32,269,474, 11 genes, copy number 6 (within-gene range 4–6): RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2.
- chr10:60,139,912–80,778,088, 398 genes, copy number 5–12 (broad region; genes not listed).
- chr11:59,491,652–62,012,602, 109 genes, copy number 5–6 (broad region; genes not listed).
- chr11:62,213,427–64,451,657, 139 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:74,311,362–74,842,413, 21 genes, copy number 6 (within-gene range 4–6): P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169.
- chr12:121,918,592–122,266,494, 12 genes, copy number 7 (within-gene range 4–7): CFAP251, AC069503.1, BCL7A, AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A.
- chr14:49,768,130–49,913,760, 11 genes, copy number 8: KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP.
- chr15:45,235,930–45,421,415, 8 genes, copy number 9: AC051619.4, SLC28A2, AC051619.1, AC051619.2, RNU6-953P, GATM, AC025580.3, SPATA5L1.
- chr15:74,957,219–75,234,834, 13 genes, copy number 6 (within-gene range 4–6): SCAMP5, AC015720.2, Y_RNA, AC015720.1, PPCDC, AC113208.2, Metazoa_SRP, AC113208.1, RPL36AP45, C15orf39, AC113208.4, AC113208.5, AC113208.3.
- chr15:89,784,895–90,502,239, 40 genes, copy number 6: ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr16:10,445,309–11,679,152, 47 genes, copy number 7–17 (within-gene range 4–17): AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1, MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24, NUBP1, TVP23A, AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN.
- chr16:29,820,394–29,973,050, 10 genes, copy number 7 (within-gene range 4–7): MVP, CDIPT, AC120114.2, CDIPTOSP, SEZ6L2, ASPHD1, KCTD13, AC120114.3, AC120114.1, TMEM219.
- chr17:39,461,486–40,304,657, 37 genes, copy number 5–153: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, KRT8P34, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6.
- chr17:41,323,427–41,836,260, 36 genes, copy number 8–10 (within-gene range 3–10): TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B.
- chr17:63,381,231–63,752,097, 21 genes, copy number 5 (within-gene range 3–5): AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6, DCAF7, RNU6-288P, TACO1, AC046185.2, MAP3K3, EEF1DP7, STRADA, LIMD2, AC046185.3, AC046185.1.
- chr17:78,066,258–78,187,233, 8 genes, copy number 11: UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2, TK1.
- chr17:81,228,277–81,481,570, 19 genes, copy number 5: TEPSIN, AC027601.1, NDUFAF8, SLC38A10, AC027601.3, AC027601.4, LINC00482, TMEM105, AC027601.5, AC110285.3, AC110285.1, AC110285.5, AC110285.2, BAHCC1, AC110285.6, MIR4740, MIR3186, AC110285.4, LINC01971.
- chr19:17,152,588–17,433,724, 26 genes, copy number 5: AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3.
- chr19:28,294,093–32,244,083, 65 genes, copy number 5–11 (broad region; genes not listed).
- chr20:16,177,933–19,056,796, 70 genes, copy number 5–8 (broad region; genes not listed).
- chr20:22,343,693–40,043,889, 408 genes, copy number 5–6 (broad region; genes not listed).
- chr20:40,854,119–64,327,972, 571 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,682. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
